Somatic mutation profile of tumor specimen TARGET-20-PARXCG-09A (aliquot TARGET-20-PARXCG-09A-02D) from TARGET case TARGET-20-PARXCG, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.5 years (4,934 days).
Specimen TARGET-20-PARXCG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b389c62-773a-4bcb-8379-b552ba4bf277.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARXCG-14A (Bone Marrow Normal), aliquot TARGET-20-PARXCG-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6269fa38-e7eb-4dac-a2f5-782175d76392

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 54/252 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- WT1 | c.1354G>A p.D452N | Missense Mutation (SNP) | VAF 129/174 reads (74%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as rs28941778, CM003970, CM127190, CM910413, COSV60066459, COSV60067963; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CEBPA | c.934_936dup p.Q312dup | In Frame Ins (INS) | VAF 34/105 reads (32%) | catalogued as COSV57198430; called by mutect2, varscan2
- GATA2 | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV62002969, COSV62003176; called by muse, mutect2
